Somatic mutation profile of tumor specimen TCGA-CJ-4902-01A (aliquot TCGA-CJ-4902-01A-01D-1429-08) from TCGA case TCGA-CJ-4902, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.4 years (22,424 days).
Specimen TCGA-CJ-4902-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9fcd909-3632-4bcd-b2d3-c6f7e7379589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4902-11A (Solid Tissue Normal), aliquot TCGA-CJ-4902-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66bddddd-315c-45fc-9388-90f7dfcd797c

The open-access MAF lists 68 somatic variants for this specimen: 56 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 10, Frame Shift Del 5, Nonsense Mutation 2, Intron 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.6376T>A p.L2126M | Missense Mutation (SNP) | VAF 88/476 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57218761, COSV57233656; called by muse, mutect2, varscan2
- AKAP13 | c.2345A>G p.D782G | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63471270; called by muse, mutect2, varscan2
- AP4E1 | c.3127A>G p.K1043E | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1423951840, COSV55920599; called by muse, mutect2, varscan2
- ARHGAP31 | c.2191T>A p.S731T | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51800091; called by mutect2, varscan2
- ATP1A4 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs377309643; called by muse, mutect2, varscan2
- BRINP3 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs745308648, COSV100818636, COSV66522732; called by muse, mutect2, varscan2
- CAPN12 | c.730_731del p.S244* | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | catalogued as rs1163980990; called by pindel, varscan2
- DHX9 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778625494, COSV62362645; called by muse, mutect2, varscan2
- EFCC1 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV101460031, COSV71402231; called by muse, mutect2, varscan2
- FADS6 | c.299T>A p.I100N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59604027; called by muse, varscan2
- FBN2 | c.2939G>A p.C980Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV52548098; called by muse, mutect2, varscan2
- FOXD4L1 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52076924; called by muse, mutect2, varscan2
- FRAS1 | c.11287T>G p.F3763V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53653841; called by muse, mutect2, varscan2
- GCM1 | c.1298G>A p.C433Y | Missense Mutation (SNP) | VAF 83/404 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1255510166, COSV52524261; called by muse, mutect2, varscan2
- GJA8 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53790896; called by muse, mutect2, varscan2
- GRID1 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 52/663 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV60057322; called by muse, mutect2
- GUSB | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV59224259; called by muse, mutect2, varscan2
- HGSNAT | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65535956; called by muse, varscan2
- JAML | c.565C>A p.L189I (on ENST00000356289 / NM_001098526.2; = p.L179I on NM_153206.3) | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.182); catalogued as COSV52629906; called by muse, mutect2, varscan2
- KCNH5 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs1461051682, COSV59770436; called by muse, mutect2
- KCNJ3 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.232); catalogued as COSV54545787; called by muse, mutect2, varscan2
- KIF20A | c.2440T>C p.Y814H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs1215742921, COSV67510766; called by muse, mutect2, varscan2
- KRT19 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as COSV54182320; called by muse, mutect2, varscan2
- MEIS1 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as COSV55493025; called by muse, mutect2
- MTMR10 | c.336C>A p.N112K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.923); catalogued as COSV58730073; called by muse, mutect2, varscan2
- MUC5B | c.6083C>G p.T2028S | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.286); catalogued as COSV71596285; called by muse, mutect2, varscan2
- MYH11 | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55572328; called by muse, mutect2, varscan2
- N4BP2L2 | c.67T>G p.C23G | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV57230404; called by muse, mutect2
- NF1 | c.4384C>T p.R1462W (on ENST00000358273 / NM_001042492.3; = p.R1441W on NM_000267.3) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.937); catalogued as rs876658127, COSV62210511; ClinVar: uncertain significance; called by muse, mutect2
- P2RX2 | c.207G>T p.E69D (on ENST00000343948 / NM_170683.4; = p.E47* on NM_012226.5) | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57691887; called by muse, mutect2, varscan2
- PCED1A | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62314235; called by muse, mutect2, varscan2
- PCK1 | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60131499; called by muse, mutect2, varscan2
- PKN3 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV52580145; called by muse, mutect2
- POLR3A | c.2095G>T p.G699W | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64932265; called by muse, mutect2, varscan2
- PRSS21 | c.91+2T>G p.X31_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV50052420; called by muse, mutect2
- RPS6KA1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1328908968, COSV100943349, COSV65177536; called by muse, mutect2
- RTL1 | c.3724C>T p.R1242C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs765417912, COSV66017009; called by muse, mutect2, varscan2
- RYR3 | c.11158C>T p.R3720C (on ENST00000389232; = p.R3721C on NM_001036.6) | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs761928983, COSV66784350; called by muse, mutect2, varscan2
- STMN4 | c.420G>T p.M140I (on ENST00000265770 / NM_001283054.2; = p.M167I on NM_030795.4) | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56110444; called by muse, mutect2
- STYX | c.134T>A p.M45K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as COSV63464033; called by muse, mutect2, varscan2
- TTC30B | c.1919A>G p.H640R | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV68809856; called by muse, mutect2, varscan2
- TXNDC5 | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV65731114; called by muse, mutect2, varscan2
- USP35 | c.1499C>A p.S500Y | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV71572739, COSV71573310; called by mutect2, varscan2
- VPS54 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1217372237, COSV55445919; called by muse, mutect2, varscan2
- VWF | c.553T>A p.Y185N | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54636488; called by muse, mutect2
- ZBTB38 | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV58539816, COSV58544669; called by muse, mutect2, varscan2
- ZDHHC9 | c.40T>A p.W14R | Missense Mutation (SNP) | VAF 132/240 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64097528; called by muse, mutect2, varscan2
- ZNF646 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV56217986; called by muse, mutect2
- ZNFX1 | c.1232A>T p.Y411F | Missense Mutation (SNP) | VAF 72/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65579826; called by muse, mutect2, varscan2
- AGRN | c.1847_1851del p.G616Vfs*7 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- APOB | c.10724del p.G3575Afs*48 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | called by mutect2, pindel, varscan2
- NCAPH2 | c.787del p.E263Rfs*3 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- SEPTIN10 | c.1108_1116del p.F370_Q372del | In Frame Del (DEL) | VAF 27/264 reads (10%) | called by mutect2, pindel
- TP53I3 | c.97_99delinsTGT p.K33C | Missense Mutation (TNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse*, pindel, varscan2*
- TUBGCP5 | c.786G>C p.R262S | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VHL | c.615_616del p.I206Cfs*49 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1572C>T p.G524= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV62326254; called by muse, mutect2
- ALPK2 | c.2313T>A p.P771= | Silent (SNP) | VAF 40/225 reads (18%) | catalogued as COSV64497863; called by muse, mutect2, varscan2
- ANPEP | c.207A>G p.K69= | Silent (SNP) | VAF 49/250 reads (20%) | catalogued as COSV55595661; called by muse, mutect2, varscan2
- CCSER2 | c.78A>T p.T26= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV56513479; called by muse, mutect2, varscan2
- GSE1 | c.2367C>T p.S789= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs772214632, COSV53676700; called by muse, mutect2, varscan2
- HMBS | c.744C>A p.I248= | Silent (SNP) | VAF 56/287 reads (20%) | catalogued as COSV53830398; called by muse, mutect2, varscan2
- KCNK18 | c.21C>T p.P7= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as COSV57973483; called by muse, mutect2, varscan2
- NUP88 | c.246C>A p.R82= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV56708288; called by muse, mutect2, varscan2
- SEC13 | c.243G>T p.R81= (on ENST00000350697 / NM_183352.3; = p.R84= on NM_030673.4) | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV61602627; called by muse, mutect2
- SLC38A10 | c.309G>T p.V103= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV55849824; called by muse, mutect2, varscan2
- SLCO1A2 | c.61-472C>A | Intron (SNP) | VAF 44/197 reads (22%) | catalogued as COSV100261940; called by muse, mutect2, varscan2
- SPTB | c.6345+2896C>G | Intron (SNP) | VAF 44/359 reads (12%) | catalogued as COSV100731132; called by muse, mutect2, varscan2
